CCDI case PBBVER — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/3482fdf5-d30d-49a7-bfc1-ba217c7dbd12

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.3 years (6,319 days).

Biospecimens (2 samples)
- Sample 0DI1JT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI200: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
